Somatic mutation profile of tumor specimen MMRF_1967_1_BM_CD138pos (aliquot MMRF_1967_1_BM_CD138pos_T1_KBS5U_L07260) from MMRF case MMRF_1967, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.1 years (27,080 days).
Specimen MMRF_1967_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad3bbd84-3262-4e3f-927a-fcafc859a654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1967_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1967_1_PB_Whole_C3_KBS5U_L07261; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f82933b-ddfa-4815-8837-ea9edd73d021

The open-access MAF lists 136 somatic variants for this specimen: 59 protein-altering or splice-affecting, 11 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 35, Intron 21, Silent 11, 3'Flank 4, Nonsense Mutation 3, RNA 2, 5'UTR 2, Frame Shift Ins 1, Splice Site 1, IGR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.6814A>G p.M2272V | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1411759189; called by muse, mutect2
- B4GALNT4 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs777258039; called by muse, mutect2, varscan2
- CDC34 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1188580719; called by muse, mutect2, varscan2
- CIITA | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 126/234 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs763739028; called by muse, mutect2, varscan2
- CYSLTR2 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV56165813; called by muse, mutect2, varscan2
- DCAF4L2 | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 94/169 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV60481886; called by muse, mutect2, varscan2
- DNAH5 | c.426C>A p.D142E | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1180629207; called by muse, mutect2
- EIF3A | c.1943T>C p.L648P | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV64962048; called by muse, mutect2, varscan2
- FBN2 | c.1261C>T p.L421F | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1419124825; called by muse, mutect2, varscan2
- FER1L5 | c.4976T>C p.F1659S (on ENST00000623019; = p.F1632S on NM_001293083.2) | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.045); catalogued as rs759625208; called by muse, mutect2, varscan2
- GAL3ST1 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 93/95 reads (98%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as rs1483769724, COSV58893362; called by muse, mutect2, varscan2
- IGHV1-69D | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1367696485; called by muse, mutect2, varscan2
- IGHV2-70 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs373390524; called by muse, varscan2
- IGHV2-70 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs374665565; called by muse, varscan2
- IGHV3-30 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 78/402 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs775263481; called by muse, varscan2
- IGHV4-34 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs753526495; called by muse, varscan2
- KMT2D | c.5038G>C p.E1680Q | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV56475694; called by muse, mutect2
- NDUFAB1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99141444; called by muse, mutect2, varscan2
- PCDH17 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 120/243 reads (49%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.899); catalogued as rs1313728820, COSV64974256; called by muse, mutect2, varscan2
- PCDHB8 | c.1210C>A p.L404I | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.764); catalogued as rs1370663255, COSV99176837; called by muse, mutect2, varscan2
- PEF1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs201297417, COSV65484160; called by muse, mutect2, varscan2
- PHYHD1 | c.767C>T p.S256L (on ENST00000372592 / NM_001100876.2; = p.R249C on NM_174933.4) | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200224549, COSV100455036, COSV58283446; called by muse, mutect2, varscan2
- PRX | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); catalogued as rs112973322; called by muse, mutect2, varscan2
- PYGO1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 215/674 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs564470411, COSV57347357; called by muse, mutect2, varscan2
- RPL10 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50010499; called by muse, mutect2, varscan2
- SLC7A13 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs139761067; called by muse, mutect2, varscan2
- SMPD4 | c.1079C>T p.T360M (on ENST00000409031 / NM_017951.4; = p.T331M on NM_017751.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs202201383; called by muse, varscan2
- SYT3 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV58897613; called by muse, mutect2, varscan2
- ADGRL3 | c.2135A>T p.N712I (on ENST00000506720 / NM_001322402.2; = p.N644I on NM_015236.6) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AGPAT4 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2
- BIVM-ERCC5 | c.2138C>T p.S713L | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- BNIP3 | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- CCND1 | c.417A>G p.Q139= | Splice Region (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- CD44 | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CENPE | c.6238dup p.R2080Kfs*5 | Frame Shift Ins (INS) | VAF 106/279 reads (38%) | called by mutect2, pindel, varscan2
- COL6A6 | c.3035A>G p.Q1012R | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CUBN | c.1850T>A p.V617D | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2
- CYP1A1 | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM155B | c.301_302insTGCCCC p.L99_P100dup | In Frame Ins (INS) | VAF 20/24 reads (83%) | called by mutect2, pindel, varscan2
- FASN | c.2136G>T p.W712C | Missense Mutation (SNP) | VAF 90/173 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAO2 | c.675G>C p.L225F | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HUWE1 | c.5884G>A p.A1962T | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- IGHV2-70D | c.245C>G p.T82R | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- IGHV4-34 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- IGSF5 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRIT1 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KTN1 | c.1030G>T p.V344L | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGEB6 | c.1205C>A p.A402E | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MUC16 | c.6054T>A p.N2018K | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- PEG3 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 95/177 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PLAT | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PSMA8 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SPINK7 | c.213-2A>T p.X71_splice | Splice Site (SNP) | VAF 21/186 reads (11%) | called by muse, mutect2, varscan2
- TNFRSF11B | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 64/121 reads (53%) | called by muse, mutect2, varscan2
- TRAF3 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 31/98 reads (32%) | called by muse, varscan2
- TSPAN10 | c.289G>T p.G97C (on ENST00000574882 / NM_001290212.1; = p.G59C on NM_031945.4) | Missense Mutation (SNP) | VAF 97/248 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- TXNRD1 | c.56C>A p.T19K | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- UHRF1BP1 | c.1928T>G p.F643C | Missense Mutation (SNP) | VAF 115/259 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDFY3 | c.7471C>T p.R2491* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- ASH1L | c.7722A>G p.E2574= (on ENST00000368346 / NM_001366177.2; = p.E2569= on NM_018489.3) | Silent (SNP) | VAF 135/310 reads (44%) | called by muse, mutect2, varscan2
- DLGAP4 | c.1143C>A p.S381= | Silent (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- DST | c.4863G>A p.L1621= | Silent (SNP) | VAF 78/167 reads (47%) | catalogued as rs201695666; called by muse, mutect2, varscan2
- FEZF2 | c.1206C>T p.Y402= | Silent (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- GTF3C1 | c.4296G>A p.L1432= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- IGHV2-70 | c.216T>A p.I72= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs561807610; called by muse, varscan2
- SLC4A11 | c.1080C>T p.D360= | Silent (SNP) | VAF 66/228 reads (29%) | catalogued as rs757729765; called by muse, mutect2, varscan2
- SPAG8 | c.21G>T p.T7= | Silent (SNP) | VAF 104/207 reads (50%) | called by muse, mutect2, varscan2
- STEAP3 | c.1257C>T p.F419= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as rs546900400; called by muse, mutect2, varscan2
- TRIL | c.2268C>A p.S756= | Silent (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- ZNF470 | c.453C>T p.N151= | Silent (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- AC091951.3 | n.725+652C>G | Intron (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- AL512649.1 | n.501C>T | RNA (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- ALDH1L2 | c.*20A>G | 3'UTR (SNP) | VAF 155/299 reads (52%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25166967 del A | 3'Flank (DEL) | VAF 26/73 reads (36%) | catalogued as rs933904670; called by mutect2, varscan2
- APPL1 | c.*2410G>C | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- ATP6AP1L | n.2093_2094insT | RNA (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- BICC1 | c.*2510T>A | 3'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- BLOC1S6 | c.*2467C>A | 3'UTR (SNP) | VAF 34/136 reads (25%) | called by muse, mutect2, varscan2
- C11orf87 | c.*1975G>A | 3'UTR (SNP) | VAF 42/135 reads (31%) | catalogued as rs1161880936; called by muse, mutect2, varscan2
- C2CD2 | c.493-40G>C | Intron (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- C2orf68 | c.*219T>A | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- C2orf68 | c.227-724G>A | Intron (SNP) | VAF 19/38 reads (50%) | catalogued as rs1006326926; called by muse, mutect2, varscan2
- CASP10 | c.685-3243G>A | Intron (SNP) | VAF 41/85 reads (48%) | catalogued as rs761039791, COSV53777772; called by muse, mutect2, varscan2
- CBY2 | c.156+565C>T | Intron (SNP) | VAF 61/126 reads (48%) | called by muse, mutect2, varscan2
- CCDC50 | c.*2513C>T | 3'UTR (SNP) | VAF 49/150 reads (33%) | called by muse, mutect2, varscan2
- CSDC2 | c.*1480C>G | 3'UTR (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2936476 G>A | 3'Flank (SNP) | VAF 53/100 reads (53%) | catalogued as rs1006030711; called by muse, mutect2, varscan2
- DCUN1D1 | c.*6755A>G | 3'UTR (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- EOGT | c.924+23G>C | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- FAM193B | c.210+69G>T | Intron (SNP) | VAF 43/65 reads (66%) | called by muse, mutect2, varscan2
- GFRA1 | c.*969G>A | 3'UTR (SNP) | VAF 13/13 reads (100%) | catalogued as rs929119988; called by muse, mutect2
- GRIK2 | c.*1111C>G | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- H2BC21 | c.*238G>C | 3'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102599G>T | Intron (SNP) | VAF 64/171 reads (37%) | catalogued as rs1049547499; called by muse, mutect2, varscan2
- IMPACT | c.36+146T>A | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- KCTD20 | c.*1462A>G | 3'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- LIG3 | c.*4439T>A | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- LMBR1L | c.72+641del | Intron (DEL) | VAF 79/193 reads (41%) | called by mutect2, pindel, varscan2
- MAFB | c.*1519C>T | 3'UTR (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92993C>T | Intron (SNP) | VAF 49/163 reads (30%) | catalogued as rs149114230; called by muse, mutect2, varscan2
- MTA2 | c.-328C>G | 5'UTR (SNP) | VAF 16/37 reads (43%) | catalogued as rs878904404; called by muse, mutect2, varscan2
- NEIL1 | c.719-137C>T | Intron (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- NME1 | c.-5+497del | Intron (DEL) | VAF 8/49 reads (16%) | catalogued as rs201290301, COSV50148304; called by pindel, varscan2
- OBSCN | c.18662-2365C>T | Intron (SNP) | VAF 65/155 reads (42%) | catalogued as rs376946873; called by muse, mutect2, varscan2
- PABPC5 | c.*495G>T | 3'UTR (SNP) | VAF 61/63 reads (97%) | catalogued as COSV57041033; called by muse, mutect2, varscan2
- PANK3 | c.*2936G>T | 3'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- PARP15 | c.*1647C>T | 3'UTR (SNP) | VAF 48/288 reads (17%) | called by muse, mutect2, varscan2
- PDE4B | chr1:66374475 T>C | 3'Flank (SNP) | VAF 10/59 reads (17%) | catalogued as rs1246660106; called by muse, mutect2, varscan2
- PDE6C | c.*246A>G | 3'UTR (SNP) | VAF 26/31 reads (84%) | called by muse, mutect2, varscan2
- PHC2 | c.*310C>A | 3'UTR (SNP) | VAF 33/129 reads (26%) | called by muse, mutect2, varscan2
- PHTF2 | c.*1762G>T | 3'UTR (SNP) | VAF 43/103 reads (42%) | called by muse, mutect2, varscan2
- PIGQ | chr16:567567 T>C | 5'Flank (SNP) | VAF 107/230 reads (47%) | catalogued as rs1292020060; called by muse, mutect2, varscan2
- QDPR | c.629+524C>T | Intron (SNP) | VAF 8/106 reads (8%) | catalogued as rs963094286; called by muse, mutect2
- RAB40C | c.*1255dup | 3'UTR (INS) | VAF 74/211 reads (35%) | called by mutect2, pindel, varscan2
- SLC35E3 | c.*1813A>G | 3'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as rs1384198949; called by muse, mutect2, varscan2
- SLC4A7 | c.*3320C>T | 3'UTR (SNP) | VAF 45/78 reads (58%) | called by muse, mutect2, varscan2
- SLC4A7 | c.*1566G>T | 3'UTR (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- TAGLN | c.-12-401T>G | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- TGFBRAP1 | chr2:105264653 C>T | 3'Flank (SNP) | VAF 38/83 reads (46%) | catalogued as rs1046071885; called by muse, mutect2, varscan2
- TMC5 | c.1049-3644C>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- TMED3 | c.*266G>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- TMEM30B | c.*349T>G | 3'UTR (SNP) | VAF 66/144 reads (46%) | called by muse, mutect2, varscan2
- TRIM58 | c.*131T>C | 3'UTR (SNP) | VAF 101/192 reads (53%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.2713-103_2713-82del | Intron (DEL) | VAF 42/73 reads (58%) | called by mutect2, pindel, varscan2
- USP3 | c.284+7504G>A | Intron (SNP) | VAF 54/852 reads (6%) | called by muse, mutect2
- Unknown | chr7:35185980 C>T | IGR (SNP) | VAF 36/65 reads (55%) | catalogued as rs1562551143; called by muse, mutect2, varscan2
- VAMP4 | c.*1932C>T | 3'UTR (SNP) | VAF 63/126 reads (50%) | catalogued as rs866516558; called by muse, mutect2, varscan2
- VNN3 | c.-42A>C | 5'UTR (SNP) | VAF 126/284 reads (44%) | called by muse, mutect2, varscan2
- VWA5A | c.*296C>A | 3'UTR (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- XYLT1 | c.*850G>A | 3'UTR (SNP) | VAF 54/90 reads (60%) | called by muse, mutect2, varscan2
- YPEL1 | c.117+140T>C | Intron (SNP) | VAF 10/11 reads (91%) | called by muse, mutect2, varscan2
- ZC3H3 | c.1716-9081G>A | Intron (SNP) | VAF 34/66 reads (52%) | catalogued as rs966670343; called by muse, mutect2, varscan2
- ZNF544 | c.*94G>A | 3'UTR (SNP) | VAF 24/49 reads (49%) | catalogued as rs960328717; called by muse, mutect2, varscan2
- ZNF697 | c.*615del | 3'UTR (DEL) | VAF 34/115 reads (30%) | called by mutect2, pindel, varscan2
- ZNF813 | c.*2482G>A | 3'UTR (SNP) | VAF 9/30 reads (30%) | catalogued as rs536441977; called by muse, mutect2, varscan2
- ZNF816 | c.*10C>A | 3'UTR (SNP) | VAF 14/464 reads (3%) | called by muse, mutect2
